Somatic mutation profile of tumor specimen ALCH-AC08-TTP1-A (aliquot ALCH-AC08-TTP1-A-2-0-D-A491-36) from ALCHEMIST case ALCH-AC08, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.2 years (23,799 days).
Specimen ALCH-AC08-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba15153-ec98-40b7-91bf-d4c475c38c45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC08-NB1-A (Blood Derived Normal), aliquot ALCH-AC08-NB1-A-1-0-D-A491-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59ba4248-76a1-47b8-989d-7d39ed5b9401

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 5, Frame Shift Del 3, 5'UTR 2, RNA 2, Splice Site 2, In Frame Del 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 297/723 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 222/828 reads (27%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- CACNA1E | c.5926G>A p.V1976M | Missense Mutation (SNP) | VAF 156/419 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs547396023, COSV62411589; called by muse, mutect2, varscan2
- CDH4 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777439660, COSV64649698; called by muse, mutect2, varscan2
- CHRM2 | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 492/1236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100281797; called by muse, mutect2, varscan2
- CPAMD8 | c.4392+2C>T p.X1464_splice (on ENST00000651564; = p.X1417_splice on NM_015692.5) | Splice Site (SNP) | VAF 64/147 reads (44%) | catalogued as rs376749112; called by muse, mutect2, varscan2
- CSF2RB | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 28/644 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1314710496; called by muse, mutect2
- DMD | c.1971A>T p.K657N | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs796762288; called by muse, mutect2
- H2AC4 | c.363_364del p.S123Pfs*3 | Frame Shift Del (DEL) | VAF 83/296 reads (28%) | catalogued as rs766399143; called by mutect2, pindel, varscan2
- HEPH | c.3175C>A p.L1059I (on ENST00000343002; = p.L792I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/380 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs775723129; called by muse, mutect2, varscan2
- KIF21A | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769811096; called by muse, mutect2
- LEPR | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 224/545 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.312); catalogued as COSV100756619; called by muse, mutect2, varscan2
- LRP1 | c.11990C>T p.S3997L | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs908851844, COSV54508232; called by muse, mutect2
- MGAT4C | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs140682310; called by muse, mutect2, varscan2
- NCAN | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370512552; called by muse, mutect2, varscan2
- OR2AK2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 195/448 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV63552670; called by muse, mutect2, varscan2
- PCLO | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 160/411 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1281951299, COSV61650048; called by muse, mutect2, varscan2
- PIK3C2G | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1388591295; called by muse, mutect2
- PPP1R13B | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 151/405 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as rs573719037; called by muse, mutect2, varscan2
- PRRC2C | c.5338C>G p.P1780A (on ENST00000367742; = p.P1778A on NM_015172.4) | Missense Mutation (SNP) | VAF 236/537 reads (44%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1355806448; called by muse, mutect2, varscan2
- PTPRD | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs772631459, COSV61932707; called by muse, mutect2
- TNN | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756201027, COSV99511134; called by muse, mutect2, varscan2
- USP54 | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 55/538 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100161310; called by muse, mutect2
- WDR90 | c.1535T>G p.V512G | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53468241; called by muse, mutect2
- ZFPM2 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as COSV68281536; called by muse, mutect2, varscan2
- ADGRE5 | c.1844T>C p.V615A (on ENST00000242786 / NM_078481.4; = p.V522A on NM_001784.5) | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- COL4A6 | c.3684A>T p.K1228N | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CROCC2 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DYNC1H1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 18/566 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.36); called by muse, mutect2
- ERBB4 | c.2741T>G p.M914R | Missense Mutation (SNP) | VAF 183/426 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM151A | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- GRPR | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HES2 | c.426del p.A143Pfs*85 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- MED12 | c.3354+1G>T p.X1118_splice | Splice Site (SNP) | VAF 145/419 reads (35%) | called by muse, mutect2, varscan2
- MIEF1 | c.186_205delinsT p.L63Gfs*15 | Frame Shift Del (DEL) | VAF 82/284 reads (29%) | called by pindel, varscan2*
- NAV3 | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 68/813 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- PCDH9 | c.1561A>T p.T521S | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PTPRF | c.5062G>A p.G1688S | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TKTL2 | c.810A>T p.R270S | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ZNF737 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AP1M1 | c.639C>G p.G213= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1887G>T p.L629= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- BPTF | c.7770C>T p.P2590= | Silent (SNP) | VAF 380/971 reads (39%) | called by muse, mutect2, varscan2
- COL6A6 | c.1458G>A p.L486= | Silent (SNP) | VAF 27/341 reads (8%) | catalogued as COSV62020738; called by muse, mutect2
- CUBN | c.5130C>T p.S1710= | Silent (SNP) | VAF 111/1334 reads (8%) | catalogued as rs750798030, COSV64726949; called by muse, mutect2
- DDHD2 | c.657A>G p.V219= | Silent (SNP) | VAF 101/302 reads (33%) | called by muse, mutect2, varscan2
- FZD6 | c.1806G>A p.A602= | Silent (SNP) | VAF 23/510 reads (5%) | catalogued as rs753220831, COSV62471912; called by muse, mutect2
- POTEE | c.150C>T p.D50= | Silent (SNP) | VAF 60/1586 reads (4%) | catalogued as rs746986270; called by muse, mutect2
- SLC24A2 | c.606C>T p.N202= | Silent (SNP) | VAF 41/704 reads (6%) | catalogued as rs147285634, COSV53864646; called by muse, mutect2
- ZFP90 | c.1617G>A p.S539= | Silent (SNP) | VAF 18/171 reads (11%) | catalogued as rs201511608; called by muse, mutect2, varscan2
- AC108676.1 | n.164G>A | RNA (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- C16orf74 | c.29-32C>T | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs965389118; called by muse, mutect2, varscan2
- CCDC69 | c.-66C>A | 5'UTR (SNP) | VAF 21/67 reads (31%) | called by mutect2, varscan2
- LINC02118 | n.106C>T | RNA (SNP) | VAF 147/440 reads (33%) | catalogued as rs536516244; called by muse, mutect2, varscan2
- MCOLN3 | c.1095+12C>T | Intron (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- NDUFA3 | c.11-11C>G | Intron (SNP) | VAF 114/241 reads (47%) | called by muse, mutect2, varscan2
- NLGN4X | c.473-3275C>T | Intron (SNP) | VAF 110/258 reads (43%) | catalogued as COSV52022483; called by muse, mutect2, varscan2
- RGS4 | c.-54A>G | 5'UTR (SNP) | VAF 225/909 reads (25%) | called by muse, mutect2, varscan2
- TSC2 | c.1840-12T>G | Intron (SNP) | VAF 225/589 reads (38%) | called by muse, mutect2, varscan2
- VSIG4 | c.*108C>T | 3'UTR (SNP) | VAF 46/1054 reads (4%) | catalogued as rs184751040; called by muse, mutect2
